Somatic mutation profile of tumor specimen TARGET-10-PAPDKD-09A (aliquot TARGET-10-PAPDKD-09A-01D) from TARGET case TARGET-10-PAPDKD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (846 days).
Specimen TARGET-10-PAPDKD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a257c3a3-e821-4a19-8d6d-8f4c0b197497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDKD-10A (Blood Derived Normal), aliquot TARGET-10-PAPDKD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccc2a0d5-bbf8-4527-8a37-c61a9d6ff87a

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, 3'UTR 2, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGAD | c.3184G>A p.V1062M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as rs777729629; called by muse, mutect2, varscan2
- PCDHGA2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV99534674; called by muse, mutect2
- RNF6 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs773110541, COSV60420191; called by muse, mutect2, varscan2
- VWA5B2 | c.1630dup p.R544Pfs*59 | Frame Shift Ins (INS) | VAF 22/96 reads (23%) | catalogued as rs1265520140; called by mutect2, pindel, varscan2
- ATG2A | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC43 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CORIN | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by mutect2, varscan2
- NDNF | c.14A>G p.H5R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF462 | c.4758C>T p.H1586= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs781596783; called by muse, mutect2, varscan2
- AVPR1A | c.*2071C>G | 3'UTR (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- BCO2 | c.518-62G>A | Intron (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- COX6B1 | c.*90C>T | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- CREB3L2 | c.103-28250G>A | Intron (SNP) | VAF 8/118 reads (7%) | catalogued as rs1188099705; called by muse, mutect2
